Somatic mutation profile of tumor specimen TCGA-DU-A5TP-01A (aliquot TCGA-DU-A5TP-01A-11D-A289-08) from TCGA case TCGA-DU-A5TP, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.2 years (12,111 days).
Specimen TCGA-DU-A5TP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bc66ffd-3634-486e-9898-284baeed40bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TP-10A (Blood Derived Normal), aliquot TCGA-DU-A5TP-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3316ca8f-d081-4bc6-86dc-d2295711b579

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 24/33 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309310, COSV63309316; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 35/41 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AIRE | c.1103del p.P368Rfs*10 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as COSV52398550; called by mutect2, pindel, varscan2
- ATF7IP2 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 12/131 reads (9%) | catalogued as COSV61092751; called by muse, mutect2, varscan2
- ATRX | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 46/59 reads (78%) | catalogued as COSV64873866; called by muse, mutect2, varscan2
- BTBD11 | c.2357G>A p.R786H (on ENST00000280758 / NM_001018072.2; = p.R323H on NM_001017523.2) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs762352277, COSV55019199; called by muse, mutect2, varscan2
- CBLL1 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV56028485; called by muse, mutect2, varscan2
- CNOT4 | c.1639T>C p.S547P (on ENST00000541284 / NM_001190850.1; = p.S544P on NM_001190849.2) | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV64157050; called by muse, mutect2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs553532837; called by mutect2, varscan2
- DRD5 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV58577425; called by muse, mutect2
- EVL | c.148G>A p.V50I (on ENST00000402714 / NM_001330221.2; = p.V52I on NM_016337.3) | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1470057216, COSV67374697; called by muse, mutect2, varscan2
- FGG | c.602A>T p.N201I | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.08); catalogued as COSV100271963, COSV60194902; called by muse, mutect2, varscan2
- GABRB2 | c.872A>G p.H291R | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV50905879; called by muse, mutect2, varscan2
- GNAI1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV63522245; called by muse, mutect2, varscan2
- HERC2 | c.5420A>G p.N1807S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV55315532; called by muse, mutect2
- MDGA2 | c.2095G>T p.A699S (on ENST00000399232 / NM_001113498.2; = p.A401S on NM_182830.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV62084512; called by muse, mutect2, varscan2
- MRPS26 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55661500; called by muse, mutect2, varscan2
- OCA2 | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62342185; called by muse, mutect2
- PA2G4 | c.711C>T p.A237= | Splice Region (SNP) | VAF 33/78 reads (42%) | catalogued as COSV57567896; called by muse, mutect2, varscan2
- PRAMEF14 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1221681902; called by muse, mutect2, varscan2
- RAB6D | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV72151640; called by muse, mutect2, varscan2
- TAF2 | c.2809A>C p.T937P | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV65417400; called by muse, mutect2
- TAS2R41 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV101281519; called by muse, mutect2
- TNC | c.3733A>T p.T1245S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as COSV60782976; called by muse, mutect2, varscan2
- UGT3A1 | c.1297T>C p.Y433H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57096977; called by muse, mutect2, varscan2
- FES | c.2280C>T p.P760= | Silent (SNP) | VAF 199/516 reads (39%) | catalogued as COSV60997496; called by muse, mutect2, varscan2
- ITGAE | c.1551G>A p.E517= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV53989097; called by muse, mutect2, varscan2
- PON1 | c.477C>A p.I159= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55931241, COSV55932284; called by muse, mutect2, varscan2
- SPPL2C | c.261G>T p.R87= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV61292087; called by muse, mutect2, varscan2
- TBC1D8B | c.1515T>C p.N505= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV52177323; called by muse, mutect2, varscan2
